Somatic mutation profile of tumor specimen TCGA-B0-4818-01A (aliquot TCGA-B0-4818-01A-01D-1501-10) from TCGA case TCGA-B0-4818, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 68.0 years (24,853 days).
Specimen TCGA-B0-4818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23bc2ba5-ed34-4686-9b74-7d798d2cc1a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4818-11A (Solid Tissue Normal), aliquot TCGA-B0-4818-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bba1c144-aa83-4c41-807e-2b776dca6f6e

The open-access MAF lists 72 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Frame Shift Del 6, Frame Shift Ins 5, Nonsense Mutation 2, 3'UTR 2, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BZW2 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51754271; called by muse, mutect2, varscan2
- C9orf64 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59032225; called by muse, mutect2, varscan2
- CCDC142 | c.1886G>A p.R629H (on ENST00000393965 / NM_001365575.2; = p.R622H on NM_032779.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.538); catalogued as rs145034743, COSV99251988; called by muse, mutect2, varscan2
- CCDC170 | c.1914A>C p.K638N | Missense Mutation (SNP) | VAF 89/382 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV53337828, COSV53342516; called by muse, mutect2, varscan2
- CCDC65 | c.794del p.I265Nfs*8 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as COSV99872738; called by mutect2, pindel
- CELF6 | c.1383A>T p.Q461H | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54715606; called by muse, mutect2, varscan2
- CEP68 | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV53123833; called by muse, mutect2, varscan2
- CEP76 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV50865780; called by muse, mutect2, varscan2
- EFHC2 | c.866C>A p.P289Q | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69553019; called by muse, mutect2, varscan2
- EHHADH | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV51628375; called by muse, mutect2, varscan2
- FAAH2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66506013; called by muse, mutect2, varscan2
- FGF13 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV59543632; called by muse, mutect2, varscan2
- GPT2 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 61/295 reads (21%) | catalogued as COSV60837741; called by muse, mutect2, varscan2
- H1-2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs746494230, COSV59189969; called by muse, mutect2, varscan2
- HACD2 | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV67322291; called by muse, mutect2, varscan2
- HERC2 | c.8548G>T p.V2850L | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55312254; called by muse, mutect2, varscan2
- HMCN1 | c.14438T>C p.V4813A | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV54884095; called by muse, mutect2
- ITGA6 | c.2788A>G p.N930D (on ENST00000442250; = p.N891D on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1559151408, COSV51220369; called by muse, mutect2, varscan2
- KLHL25 | c.458T>C p.M153T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV61994434; called by muse, mutect2
- KYAT3 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53099202; called by muse, mutect2, varscan2
- LPP | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV57082303; called by muse, mutect2, varscan2
- MPDZ | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV59936938; called by muse, mutect2, varscan2
- NOS1AP | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62632812; called by muse, mutect2, varscan2
- OR4C12 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.327); catalogued as COSV58859588; called by muse, mutect2, varscan2
- PBRM1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56265395; called by muse, mutect2
- PBRM1 | c.2576C>A p.S859* | Nonsense Mutation (SNP) | VAF 49/176 reads (28%) | catalogued as COSV56265416, COSV99046502; called by muse, mutect2
- PLEKHA5 | c.3057A>T p.E1019D | Missense Mutation (SNP) | VAF 98/410 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV54695960; called by muse, mutect2, varscan2
- PROKR2 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54085613; called by muse, mutect2, varscan2
- PTDSS1 | c.884T>A p.I295N | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61263866; called by muse, mutect2, varscan2
- R3HDM1 | c.1972C>A p.Q658K | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51521902; called by muse, mutect2, varscan2
- SEPTIN11 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV53580946; called by muse, mutect2, varscan2
- SLC5A3 | c.880del p.H294Mfs*12 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as COSV62969530; called by mutect2, pindel, varscan2
- SNCAIP | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV54404342; called by muse, mutect2, varscan2
- SOX30 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV53936449; called by muse, mutect2, varscan2
- SRCAP | c.6793G>T p.V2265L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV52668853; called by muse, varscan2
- SYNE4 | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61010160; called by mutect2, varscan2
- TAF1 | c.2546G>A p.R849H (on ENST00000373790 / NM_138923.4; = p.R870H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/487 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52108870; called by muse, mutect2
- TBC1D8 | c.3418T>A p.L1140M | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.085); catalogued as COSV51821170; called by muse, mutect2, varscan2
- TDRD7 | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 89/359 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV62428717; called by muse, mutect2, varscan2
- TDRD7 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV62428723; called by muse, mutect2, varscan2
- TMEM145 | c.848A>C p.Y283S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs781522825, COSV56624142, COSV56625008; called by muse, mutect2, varscan2
- TNC | c.2576C>A p.S859Y | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60781755; called by muse, mutect2, varscan2
- TOGARAM1 | c.1933T>A p.C645S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV61887580; called by muse, mutect2, varscan2
- TOPORS | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62116400; called by muse, mutect2, varscan2
- UBR1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51927359; called by muse, mutect2, varscan2
- VHL | c.640dup p.*214Lfs*42 | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | catalogued as COSV56561006; called by mutect2, pindel, varscan2
- ACSM3 | c.1372_1373insAA p.I458Kfs*37 | Frame Shift Ins (INS) | VAF 125/625 reads (20%) | called by mutect2, pindel, varscan2
- FMO2 | c.1046_1047insA p.M349Ifs*6 | Frame Shift Ins (INS) | VAF 35/178 reads (20%) | called by mutect2, pindel, varscan2
- KHDC4 | c.1013-2_1013-1insAA p.X338_splice | Splice Site (INS) | VAF 34/195 reads (17%) | called by mutect2, pindel, varscan2
- KLC3 | c.1150_1151insGG p.A384Gfs*4 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- KLC3 | c.1151delinsGGG p.A384Gfs*4 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2*, pindel, varscan2*
- SS18 | c.566del p.N189Tfs*8 | Frame Shift Del (DEL) | VAF 111/542 reads (20%) | called by mutect2, pindel, varscan2
- TCP11L1 | c.51del p.K17Nfs*24 | Frame Shift Del (DEL) | VAF 73/316 reads (23%) | called by mutect2, pindel, varscan2
- TTN | c.67825_67832del p.G22609* (on ENST00000591111; = p.G15185* on NM_003319.4) | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | called by mutect2, pindel, varscan2
- TTN | c.48000del p.K16000Nfs*4 (on ENST00000591111; = p.K8576Nfs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | called by mutect2, pindel, varscan2
- ABCB6 | c.2010C>G p.P670= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV54693765; called by muse, mutect2
- BFSP2 | c.87G>A p.G29= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs750860569, COSV56587123, COSV56589785; called by muse, mutect2
- CCDC186 | c.1545A>T p.T515= | Silent (SNP) | VAF 132/633 reads (21%) | catalogued as COSV65160792; called by muse, mutect2, varscan2
- CRYL1 | c.255A>G p.V85= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV53417045; called by muse, mutect2, varscan2
- EXOC6B | c.2295G>C p.L765= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV55547743; called by muse, mutect2, varscan2
- HAO2 | c.63T>C p.T21= | Silent (SNP) | VAF 73/351 reads (21%) | catalogued as COSV58038283; called by muse, mutect2, varscan2
- NUP98 | c.5109C>T p.L1703= (on ENST00000359171 / NM_001365126.1; = p.L1686= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as rs1018337022, COSV61429700; called by muse, mutect2, varscan2
- PIGG | c.2163G>A p.K721= (on ENST00000453061 / NM_001127178.3; = p.K713= on NM_017733.4) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV56316758; called by muse, mutect2, varscan2
- R3HDM1 | c.1971T>A p.P657= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV51521890; called by muse, mutect2, varscan2
- SORT1 | c.1083A>G p.V361= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV56664903; called by muse, mutect2, varscan2
- ST8SIA3 | c.1125T>A p.T375= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV60653554; called by muse, mutect2, varscan2
- UTP14A | c.396A>T p.V132= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV64086379; called by muse, mutect2, varscan2
- VEGFA | c.90A>G p.A30= (on ENST00000523873 / NM_001171623.1; = p.A210= on NM_003376.6) | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV57877911; called by mutect2, varscan2
- AGAP7P | n.1709A>T | RNA (SNP) | VAF 34/299 reads (11%) | called by muse, mutect2, varscan2
- DLG2 | c.1978+854C>T | Intron (SNP) | VAF 17/139 reads (12%) | catalogued as COSV99712742; called by muse, mutect2, varscan2
- NPR3 | c.*3124G>T | 3'UTR (SNP) | VAF 33/97 reads (34%) | catalogued as COSV54085300; called by muse, mutect2, varscan2
- RALGAPA1 | c.*135A>G | 3'UTR (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99353334; called by muse, mutect2, varscan2
